Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8AA, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8AA-01A (Primary Tumor).

[page 1 of 2]
Panel: Surgical Pathology Final Report

Date:

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-In progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
Surgical Pathology Final Report	██████████ F ██████████	██████████				
Collection d/t:						
Obs d/t:						
Ordered by:						

Surgical Pathology Report

ICD-O-3
Seminoma NOS 9061/3
Site: R Testis NOS C62.9
70 6/30/14

Final Diagnosis

1. Right testicle, 31.7 g, right radical orchiectomy:
- A. Classical seminoma, 1.5 cm, confined to the testis. The tumor invades the tunica albuginea and the rete testis. No involvement of the tunica vaginalis seen. No lymphovascular invasion identified.
- B. The spermatic cord and spermatic cord margin are free of tumor.

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Pathologist(s)

Gross Description

Specimen #1 designated "right testicle" is received fresh, labeled with the patient's name and medical record number and consists of a testicle weighing 31.7 g and measuring 5.5 x 3.8 x 1.4 cm. The spermatic cord is identified and measures 9.5 x 0.3 cm. The external surface is inked entirely in blue. The testicle is bivalved to reveal a well-circumscribed, ovoid mass with a white-tan rim and a pink red inner core altogether measuring 1.5 x 1.2 x 1.0 cm. The mass is located at the most distal aspect of the testicle and is far removed from the spermatic cord. Representative sections are submitted as follows: 1A, spermatic cord margin; 1B through 1F, tumor submitted in toto; 1G and 1H, unremarkable testicle and rete testis.

[page 2 of 2]
SUMMARY OF SECTIONS: 8, multiple, representative

Dictated by:

Clinical Information

year-old man with right testicular mass
Past medical history: Asthma, right inguinal hernia repair, orchiopexy in
vasectomy
Pre-Operative Diagnosis: Not specified
Post-Operative Diagnosis: Not specified
Operation: Right radical orchiectomy
Specific questions to be answered: None

Specimen:

1 Right testicle

*** End of report ***

Source: NCI Genomic Data Commons file 4a2cdaee-3112-437d-ade4-c41fb4abd848 (TCGA-VF-A8AA.347D6A7E-9A15-4230-8F0C-032410AE1403.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).